Surgical pathology report (de-identified scan), TCGA case TCGA-BR-A4J6, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-A4J6-01A (Primary Tumor).

Gross Description: Part of the stomach with part of the esophagus. In the cardia region there is a plate-like tumor up to 7.5 cm in its diameter, with invasion into the perigastric fat. In the fatty tissue of the greater and lesser curvature there are enlarged dense lymph nodes. In the omentum there are nodes (of possible metastatic nature) up to 1 cm in their diameter. Separately collected two fragments of fatty tissue without macroscopic special features. Surgical margins are free of macroscopic special features.

Microscopic Description: Adenocarcinoma of the stomach, G-2, with invasion into the perigastric fatty tissue. Tumor is spread to the esophageal wall under the squamous epithelium. Surgical margins are free of tumor elements. Lymph nodes including separately collected ones demonstrate reactive changes. Omentum is hyperemic.

Diagnosis Details: Tumor Features: Ulcerated, Tumor Extent: Perigastric fat , Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: STOMACH TISSUE CHECKLIST

Specimen type: Subtotal gastrectomy

Tumor site: Cardia

1CD-0-3

Tumor size: 0 x 0 x 7.5 cm

adenocarcinoma, NOS 8140/3

Tumor features: Ulcerated

Site: stomach, cardia, NOS C16.0

Histologic type: Adenocarcinoma

hw
10/2/12

Histologic grade: Moderately differentiated

Tumor extent: Subserosa

Lymph nodes: 0/10 positive for metastasis (Adjacent fatty tissue 0/10)

Lymphatic invasion: Not specified

Venous invasion: Absent

Perineural invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Tumor is spread to the esophageal wall under the squamous epithelium.

Comments: None

Source: NCI Genomic Data Commons file 8e15b133-68ad-4258-99c2-e393ccb6294b (TCGA-BR-A4J6.141FECBE-8D53-400C-AFEA-BE4027787253.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).